Somatic mutation profile of tumor specimen TCGA-CV-5435-01A (aliquot TCGA-CV-5435-01A-01D-1683-08) from TCGA case TCGA-CV-5435, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 57.3 years (20,926 days).
Specimen TCGA-CV-5435-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b978504b-eb25-467a-a2bd-ff97549e1ab4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-5435-10A (Blood Derived Normal), aliquot TCGA-CV-5435-10A-01D-1870-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cd313f2e-90d1-41cf-bf01-dda3590cf114

The open-access MAF lists 135 somatic variants for this specimen: 93 protein-altering or splice-affecting, 35 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 76, Silent 35, Nonsense Mutation 6, Frame Shift Del 5, RNA 4, Frame Shift Ins 2, Splice Site 2, Intron 2, Splice Region 1, 5'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLG | c.3427G>T p.G1143* | Nonsense Mutation (SNP) | VAF 14/370 reads (4%) | catalogued as rs1258394093, COSV64244580; ClinVar: pathogenic; called by muse, mutect2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 40/75 reads (53%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.272G>A p.W91* | Nonsense Mutation (SNP) | VAF 84/103 reads (82%) | hotspot (GDC flag); catalogued as COSV52734595, COSV53139118; called by muse, mutect2, varscan2
- ADAR | c.2530A>G p.I844V | Missense Mutation (SNP) | VAF 26/45 reads (58%) | SIFT tolerated (0.18); PolyPhen benign (0.069); catalogued as COSV99426188; called by muse, mutect2, varscan2
- ALG6 | c.876G>T p.L292F | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.73); PolyPhen benign (0.031); catalogued as COSV99673284; called by muse, mutect2, varscan2
- ANKS6 | c.511G>T p.D171Y | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100782315; called by muse, mutect2, varscan2
- ASPM | c.1666A>G p.K556E | Missense Mutation (SNP) | VAF 46/101 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.071); catalogued as rs756904112, COSV99660584; called by muse, mutect2, varscan2
- C7orf25 | c.627G>C p.E209D | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV100623648; called by muse, mutect2, varscan2
- CALCR | c.241T>C p.C81R | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1228575434, COSV100810602; called by muse, mutect2, varscan2
- CCT7 | c.349C>T p.H117Y | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.186); catalogued as COSV99240897; called by muse, mutect2
- CDH7 | c.2137del p.E713Kfs*3 | Frame Shift Del (DEL) | VAF 44/117 reads (38%) | catalogued as COSV59893281; called by mutect2, pindel, varscan2
- CFH | c.1612G>T p.D538Y | Missense Mutation (SNP) | VAF 29/149 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.878); catalogued as COSV100809718; called by muse, mutect2, varscan2
- CHD9 | c.7361A>G p.H2454R (on ENST00000398510 / NM_001382353.1; = p.H2438R on NM_025134.7) | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.842); catalogued as rs980229728; called by muse, mutect2
- CILP2 | c.1933G>A p.V645M | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.791); catalogued as rs1226316171, COSV52278384; called by muse, mutect2, varscan2
- CLIP1 | c.222C>G p.I74M | Missense Mutation (SNP) | VAF 129/185 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100211885; called by muse, mutect2, varscan2
- COL1A1 | c.991G>A p.A331T | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.475); catalogued as COSV99867456; called by muse, mutect2, varscan2
- COPB2 | c.586G>A p.G196S | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT tolerated (0.08); PolyPhen benign (0.255); catalogued as rs776914376, COSV100300695; called by muse, mutect2
- CRYBB3 | c.142C>A p.L48M | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99309097; called by muse, mutect2, varscan2
- CSMD2 | c.2122C>G p.Q708E | Missense Mutation (SNP) | VAF 37/150 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.877); catalogued as COSV99591495; called by muse, mutect2, varscan2
- CUL3 | c.337C>T p.Q113* | Nonsense Mutation (SNP) | VAF 22/33 reads (67%) | catalogued as COSV100024351; called by muse, mutect2, varscan2
- CYP4X1 | c.1491T>G p.N497K | Missense Mutation (SNP) | VAF 20/154 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.117); catalogued as COSV100903329; called by muse, mutect2, varscan2
- DDB1 | c.3065C>T p.T1022I | Missense Mutation (SNP) | VAF 100/228 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as COSV100074669; called by muse, varscan2
- DLG1 | c.940T>G p.S314A | Missense Mutation (SNP) | VAF 73/121 reads (60%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV100015488; called by muse, mutect2, varscan2
- DNAH9 | c.6982A>G p.T2328A | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV99306353; called by muse, mutect2, varscan2
- ENTPD5 | c.815G>A p.C272Y | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100592246; called by muse, mutect2, varscan2
- FAM20A | c.827G>A p.R276Q | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs147371993; called by muse, mutect2, varscan2
- FAT2 | c.6293A>G p.D2098G | Missense Mutation (SNP) | VAF 55/75 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99943267; called by muse, mutect2, varscan2
- FBF1 | c.2018C>T p.T673M (on ENST00000586717; = p.T687M on NM_001319193.1) | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.625); catalogued as rs1477391989, COSV100045265; called by muse, mutect2
- FLT1 | c.832G>A p.V278I | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs372354806; called by muse, mutect2
- GIGYF2 | c.1492A>G p.M498V | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.06); catalogued as rs1321348010, COSV101004443; called by muse, mutect2, varscan2
- GPR27 | c.1052C>T p.A351V | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT deleterious (0.01); PolyPhen benign (0.369); catalogued as COSV99816509; called by muse, mutect2, varscan2
- GPRC5B | c.1201C>T p.H401Y | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV100244939; called by muse, mutect2, varscan2
- GRIN2B | c.3109G>A p.D1037N | Missense Mutation (SNP) | VAF 27/44 reads (61%) | SIFT tolerated (0.42); PolyPhen benign (0.028); catalogued as COSV101663076; called by muse, mutect2, varscan2
- GXYLT1 | c.385G>C p.E129Q | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as COSV99788602; called by muse, mutect2, varscan2
- HLCS | c.799G>A p.V267I | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.025); catalogued as COSV100358306; called by muse, mutect2, varscan2
- IGSF21 | c.667A>C p.T223P | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); catalogued as COSV99245287; called by muse, mutect2, varscan2
- JAG1 | c.451A>G p.I151V | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV99653081; called by muse, mutect2, varscan2
- KLF15 | c.506C>T p.A169V | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as rs368953798; called by muse, mutect2, varscan2
- KLHDC7B | c.823C>T p.R275W (on ENST00000395676; = p.R916W on NM_138433.5) | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748836236, COSV101192955; called by muse, varscan2
- MACF1 | c.12872C>T p.A4291V (on ENST00000372915; = p.A2224V on NM_012090.5) | Missense Mutation (SNP) | VAF 35/87 reads (40%) | catalogued as rs573837366, COSV57104402; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MAGEA6 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.145); catalogued as COSV100262860; called by muse, mutect2, varscan2
- MOGS | c.1583C>A p.P528H | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.911); catalogued as COSV99270591; called by muse, varscan2
- MPDZ | c.3636T>A p.D1212E | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV100057002; called by muse, mutect2, varscan2
- MUC6 | c.6781G>A p.A2261T | Missense Mutation (SNP) | VAF 43/233 reads (18%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0); catalogued as rs748267272, COSV70145208; called by muse, mutect2, varscan2
- NDUFB3 | c.54T>G p.D18E | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99428315; called by muse, mutect2
- OLFM3 | c.1372A>G p.N458D (on ENST00000338858 / NM_001288821.1; = p.N438D on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 56/92 reads (61%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV100129665; called by muse, mutect2, varscan2
- OR2T33 | c.508C>A p.H170N | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV100532006; called by muse, mutect2
- OR5B17 | c.888G>T p.K296N | Missense Mutation (SNP) | VAF 21/135 reads (16%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.111); catalogued as COSV62160716; called by muse, mutect2, varscan2
- PDE7A | c.262A>G p.I88V (on ENST00000401827 / NM_001242318.3; = p.I62V on NM_002603.4) | Missense Mutation (SNP) | VAF 22/176 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.424); catalogued as COSV101052678; called by muse, mutect2, varscan2
- PFKFB2 | c.1052G>A p.R351Q | Missense Mutation (SNP) | VAF 15/86 reads (17%) | PolyPhen possibly damaging (0.723); catalogued as rs1483577508, COSV65547250; called by muse, mutect2, varscan2
- PLCB3 | c.3380G>C p.R1127P | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.892); catalogued as COSV99657497; called by muse, mutect2, varscan2
- PLCH1 | c.4404G>T p.M1468I (on ENST00000340059 / NM_001130960.2; = p.M1460I on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.001); catalogued as COSV100397230; called by muse, mutect2
- PRKAA1 | c.128-1G>C p.X43_splice | Splice Site (SNP) | VAF 37/51 reads (73%) | catalogued as COSV57186238, COSV99713313; called by muse, mutect2, varscan2
- PROCA1 | c.441-1G>A p.X147_splice (on ENST00000439862 / NM_001366301.1; = p.X119_splice on NM_152465.3 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 22/115 reads (19%) | catalogued as COSV99972539, COSV99972765; called by muse, varscan2
- PRPF4 | c.196A>G p.I66V (on ENST00000374198 / NM_001322267.2; = p.I67V on NM_004697.5) | Missense Mutation (SNP) | VAF 100/214 reads (47%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs770151743, COSV100950709; called by muse, mutect2, varscan2
- PTPRB | c.322del p.S108Lfs*11 | Frame Shift Del (DEL) | VAF 16/35 reads (46%) | catalogued as COSV51739590; called by mutect2, pindel, varscan2
- REG3G | c.127G>T p.G43C | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV55449069, COSV55450717; called by muse, mutect2
- RNF213 | c.13522G>A p.G4508S | Missense Mutation (SNP) | VAF 76/200 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs765019511, COSV100299566; called by muse, mutect2, varscan2
- RPS6KC1 | c.1891C>G p.P631A | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV100873929; called by muse, mutect2, varscan2
- SAMD9L | c.3054G>T p.E1018D | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.797); catalogued as rs376356072, COSV59085341; called by muse, mutect2, varscan2
- SIGLEC14 | c.743G>T p.G248V | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as COSV99707597; called by muse, mutect2, varscan2
- SLC16A6 | c.1336C>T p.Q446* | Nonsense Mutation (SNP) | VAF 18/72 reads (25%) | catalogued as COSV100517331; called by muse, mutect2, varscan2
- SLC25A3 | c.8C>G p.S3W | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.898); catalogued as COSV99499316; called by muse, mutect2, varscan2
- SLC52A1 | c.182G>T p.G61V | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99643452; called by muse, mutect2, varscan2
- SPDYE3 | c.1539C>A p.F513L | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.485); catalogued as COSV100193694; called by muse, mutect2, varscan2
- SRPK2 | c.349C>T p.H117Y | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100624105; called by muse, mutect2, varscan2
- SSTR3 | c.422G>A p.R141H | Missense Mutation (SNP) | VAF 69/154 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373095766, COSV100142708; called by muse, mutect2, varscan2
- THBS1 | c.2571C>G p.D857E | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV99528039; called by muse, mutect2, varscan2
- TNRC6C | c.4162G>C p.E1388Q | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100050122; called by muse, varscan2
- TPH2 | c.1133C>A p.A378E | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100422142; called by muse, mutect2, varscan2
- TRIM33 | c.1955A>T p.N652I | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT tolerated (0.44); PolyPhen benign (0.091); catalogued as COSV100635478; called by muse, mutect2, varscan2
- TTLL5 | c.3289C>G p.Q1097E | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.014); catalogued as COSV100090657; called by muse, mutect2, varscan2
- TUBA4A | c.896C>T p.A299V | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV99944766; called by muse, mutect2, varscan2
- TXK | c.589G>T p.E197* | Nonsense Mutation (SNP) | VAF 4/37 reads (11%) | catalogued as COSV51919373; called by muse, mutect2, varscan2
- UGT2A3 | c.1112C>G p.T371S | Missense Mutation (SNP) | VAF 13/18 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99279923; called by muse, mutect2, varscan2
- UNC79 | c.7406T>C p.M2469T (on ENST00000393151 / NM_001346218.2; = p.M2292T on NM_020818.5) | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.176); catalogued as COSV99828332; called by muse, mutect2, varscan2
- USP46 | c.670G>A p.E224K | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.955); catalogued as COSV101484275; called by muse, mutect2, varscan2
- VCPIP1 | c.2465C>G p.P822R | Missense Mutation (SNP) | VAF 30/165 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100125676; called by muse, mutect2, varscan2
- VPS35 | c.167C>T p.S56F | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV100140689, COSV54478314; called by muse, mutect2, varscan2
- WDR11 | c.87G>A p.W29* | Nonsense Mutation (SNP) | VAF 14/28 reads (50%) | catalogued as COSV99676671; called by muse, mutect2, varscan2
- WNT3 | c.781G>C p.A261P | Missense Mutation (SNP) | VAF 53/119 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99843311; called by muse, mutect2, varscan2
- XKR5 | c.673G>A p.A225T | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs368056834; called by muse, mutect2
- ZFP36L1 | c.734A>T p.D245V | Missense Mutation (SNP) | VAF 91/217 reads (42%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); catalogued as COSV100322739; called by muse, mutect2, varscan2
- ZNF500 | c.136C>G p.P46A | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.901); catalogued as COSV99556378; called by muse, mutect2, varscan2
- ZNF536 | c.2508C>A p.D836E | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.028); catalogued as COSV62819287; called by muse, mutect2, varscan2
- AJUBA | c.837dup p.L280Afs*26 | Frame Shift Ins (INS) | VAF 10/18 reads (56%) | called by mutect2, pindel, varscan2
- ASTE1 | c.581dup p.A195Cfs*7 | Frame Shift Ins (INS) | VAF 33/113 reads (29%) | called by mutect2, pindel, varscan2
- CCPG1 | c.1661_1702del p.A554_S567del | In Frame Del (DEL) | VAF 20/111 reads (18%) | called by mutect2, pindel
- CDKN2A | c.29_45del p.E10Afs*28 | Frame Shift Del (DEL) | VAF 4/14 reads (29%) | called by mutect2, varscan2
- MRC1 | c.2112A>T p.T704= | Splice Region (SNP) | VAF 155/300 reads (52%) | called by muse, mutect2, varscan2
- TET3 | c.991_1006del p.I331Afs*9 | Frame Shift Del (DEL) | VAF 15/31 reads (48%) | called by mutect2, pindel, varscan2
- TRBV24-1 | c.167A>G p.Q56R | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- VPS13C | c.9588_9615del p.Q3197Gfs*28 (on ENST00000644861 / NM_020821.3; = p.Q3154Gfs*28 on NM_017684.5) | Frame Shift Del (DEL) | VAF 14/56 reads (25%) | called by mutect2, pindel
- ADD2 | c.1626C>T p.D542= | Silent (SNP) | VAF 53/86 reads (62%) | catalogued as rs782116985, COSV52462765; called by muse, mutect2, varscan2
- ANKS6 | c.510G>T p.V170= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as COSV100782316; called by muse, mutect2, varscan2
- ATAD5 | c.1795A>C p.R599= | Silent (SNP) | VAF 27/128 reads (21%) | catalogued as COSV100430028; called by muse, mutect2, varscan2
- C2orf16 | c.5373C>T p.H1791= | Silent (SNP) | VAF 28/195 reads (14%) | catalogued as rs1239738193, COSV100820838; called by muse, varscan2
- CEP112 | c.2040C>T p.N680= | Silent (SNP) | VAF 24/60 reads (40%) | catalogued as rs140758713; called by muse, mutect2, varscan2
- CILP | c.1524C>T p.G508= | Silent (SNP) | VAF 4/44 reads (9%) | catalogued as rs1177351638, COSV99973546; called by muse, mutect2
- CIT | c.5373G>A p.V1791= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as rs1451274404, COSV99950018; called by muse, mutect2, varscan2
- CNTN2 | c.2226C>T p.D742= | Silent (SNP) | VAF 98/273 reads (36%) | catalogued as COSV100085147; called by muse, mutect2, varscan2
- CSMD1 | c.9465C>T p.F3155= (on ENST00000520002; = p.F3154= on NM_033225.6) | Silent (SNP) | VAF 3/20 reads (15%) | catalogued as COSV100149485; called by muse, mutect2
- ESX1 | c.876G>A p.A292= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as rs782213430, COSV101006475; called by muse, mutect2
- GAREM1 | c.2166C>T p.C722= (on ENST00000269209 / NM_001242409.2; = p.C721= on NM_022751.3) | Silent (SNP) | VAF 15/89 reads (17%) | catalogued as COSV99330826; called by muse, mutect2, varscan2
- GH2 | c.429A>G p.L143= | Silent (SNP) | VAF 42/116 reads (36%) | catalogued as COSV100237002; called by muse, mutect2, varscan2
- HNRNPF | c.825A>G p.R275= | Silent (SNP) | VAF 19/37 reads (51%) | catalogued as COSV100563137; called by muse, mutect2, varscan2
- NLGN1 | c.2355C>T p.P785= | Silent (SNP) | VAF 18/101 reads (18%) | catalogued as COSV100849464; called by muse, mutect2, varscan2
- OCA2 | c.66G>A p.T22= | Silent (SNP) | VAF 19/30 reads (63%) | catalogued as rs1430442346, COSV100668096; called by muse, mutect2, varscan2
- OR11L1 | c.639G>T p.L213= | Silent (SNP) | VAF 30/69 reads (43%) | catalogued as COSV100869443; called by muse, mutect2, varscan2
- OR5H2 | c.408A>G p.L136= | Silent (SNP) | VAF 25/104 reads (24%) | catalogued as COSV100788749; called by muse, mutect2, varscan2
- ORC2 | c.762C>G p.T254= | Silent (SNP) | VAF 8/109 reads (7%) | catalogued as COSV99309594; called by muse, mutect2
- PAXIP1 | c.1008G>A p.R336= | Silent (SNP) | VAF 21/40 reads (53%) | catalogued as COSV101249800; called by muse, mutect2, varscan2
- PCDH10 | c.1578C>T p.Y526= | Silent (SNP) | VAF 19/75 reads (25%) | catalogued as rs762454585, COSV52087266, COSV52091271; called by muse, mutect2, varscan2
- PDE3A | c.825G>A p.L275= | Silent (SNP) | VAF 19/86 reads (22%) | catalogued as rs750288734, COSV62967221; called by muse, mutect2, varscan2
- PHF20L1 | c.3051A>G p.V1017= | Silent (SNP) | VAF 24/38 reads (63%) | catalogued as rs896054751, COSV99621452; called by muse, mutect2, varscan2
- PLEKHG3 | c.2439C>T p.S813= (on ENST00000394691; = p.S869= on NM_001308147.2) | Silent (SNP) | VAF 23/43 reads (53%) | catalogued as COSV99906709; called by muse, mutect2, varscan2
- PLPPR4 | c.2133C>T p.S711= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV64565324, COSV64565634; called by muse, mutect2, varscan2
- PRKRA | c.372G>A p.Q124= | Silent (SNP) | VAF 30/63 reads (48%) | catalogued as COSV100359655; called by muse, mutect2, varscan2
- RASGRF1 | c.2595C>A p.P865= | Silent (SNP) | VAF 27/131 reads (21%) | catalogued as COSV101174565, COSV67250831; called by muse, mutect2, varscan2
- RFLNA | c.585C>T p.T195= (on ENST00000546355 / NM_001365156.1; = p.T114= on NM_181709.4) | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as rs757799479, COSV100133345; called by muse, mutect2, varscan2
- RHOJ | c.96G>C p.V32= | Silent (SNP) | VAF 18/40 reads (45%) | catalogued as COSV100370346; called by muse, mutect2, varscan2
- SEC16B | c.2055G>A p.L685= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as COSV100381670, COSV100381929; called by muse, mutect2, varscan2
- SH3RF2 | c.585C>G p.L195= | Silent (SNP) | VAF 16/28 reads (57%) | catalogued as COSV63040973; called by muse, mutect2, varscan2
- STAC2 | c.1009C>A p.R337= | Silent (SNP) | VAF 30/62 reads (48%) | catalogued as COSV100336406; called by muse, mutect2, varscan2
- TTN | c.75207T>C p.D25069= (on ENST00000591111; = p.D17645= on NM_003319.4) | Silent (SNP) | VAF 33/174 reads (19%) | catalogued as COSV100617872; called by muse, mutect2, varscan2
- TXK | c.588G>T p.T196= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as rs751767258, COSV51918092, COSV99972528; called by mutect2, varscan2
- XXYLT1 | c.840G>A p.P280= | Silent (SNP) | VAF 22/129 reads (17%) | catalogued as rs761047837, COSV59983353; called by muse, mutect2, varscan2
- ZNF431 | c.624A>G p.K208= | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as COSV100218830; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65505772 A>G | 5'Flank (SNP) | VAF 23/69 reads (33%) | catalogued as rs764852271; called by muse, mutect2, varscan2
- LINC01098 | n.751dup | RNA (INS) | VAF 25/86 reads (29%) | catalogued as rs765631673; called by mutect2, pindel, varscan2
- NBPF25P | n.871G>T | RNA (SNP) | VAF 36/238 reads (15%) | called by muse, mutect2, varscan2
- PRB1 | c.101-1517C>A | Intron (SNP) | VAF 8/67 reads (12%) | catalogued as COSV99555927; called by muse, mutect2, varscan2
- SNORD116-14 | n.9G>A | RNA (SNP) | VAF 50/101 reads (50%) | called by muse, mutect2, varscan2
- SSPOP | n.2413T>C | RNA (SNP) | VAF 43/134 reads (32%) | catalogued as COSV100022634; called by muse, varscan2
- VAPA | c.418-5446C>T | Intron (SNP) | VAF 15/42 reads (36%) | catalogued as rs776811459, COSV100486130, COSV100486135; called by muse, mutect2, varscan2
